Somatic mutation profile of tumor specimen TCGA-EI-6514-01A (aliquot TCGA-EI-6514-01A-11D-1733-10) from TCGA case TCGA-EI-6514, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma in tubulovillous adenoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 59.2 years (21,618 days).
Specimen TCGA-EI-6514-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f5ae148-4f59-4a84-93a8-844ea58db423.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EI-6514-10A (Blood Derived Normal), aliquot TCGA-EI-6514-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/430c857f-770f-4a1b-b988-b04f40874ab7

The open-access MAF lists 126 somatic variants for this specimen: 101 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 23, Nonsense Mutation 8, Frame Shift Ins 4, Splice Region 3, Splice Site 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3391C>T p.Q1131* | Nonsense Mutation (SNP) | VAF 53/108 reads (49%) | catalogued as rs878853438, CM014887, COSV57337186; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 28/36 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSS3 | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99698514; called by muse, mutect2, varscan2
- AFAP1L1 | c.168T>G p.Y56* | Nonsense Mutation (SNP) | VAF 24/81 reads (30%) | catalogued as COSV57048203; called by muse, mutect2, varscan2
- APC | c.3934G>T p.G1312* | Nonsense Mutation (SNP) | VAF 52/151 reads (34%) | catalogued as COSV57321523, COSV57355837; called by muse, mutect2, varscan2
- ARHGEF5 | c.4546C>T p.Q1516* | Nonsense Mutation (SNP) | VAF 8/122 reads (7%) | catalogued as COSV99282701; called by muse, mutect2
- ARMCX5 | c.1121G>T p.S374I | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as COSV55767879; called by muse, mutect2, varscan2
- ASPHD2 | c.520C>G p.P174A | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV53221232; called by muse, mutect2, varscan2
- ATP6V1H | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs562675599, COSV62220815; called by muse, mutect2, varscan2
- C16orf86 | c.625A>C p.K209Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV99708146; called by mutect2, varscan2
- CABYR | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs1248356232, COSV100509981; called by muse, mutect2
- CAPZA3 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as COSV56859703; called by muse, mutect2, varscan2
- CLDN18 | c.81G>A p.M27I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.181); catalogued as COSV51737658; called by muse, mutect2, varscan2
- CNKSR2 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as rs771705122, COSV54255339; called by muse, mutect2, varscan2
- CNTN3 | c.1149G>T p.M383I | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as COSV55186499; called by muse, mutect2
- COX18 | c.908A>G p.Q303R | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777276473, COSV55721489; called by muse, mutect2, varscan2
- CRYGD | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs1262452200, COSV99965266; called by muse, mutect2
- CSNK1A1L | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as rs546173732, COSV65790407; called by muse, mutect2, varscan2
- DYNC2H1 | c.11417G>A p.R3806H | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1515016, COSV62096285; called by muse, mutect2
- ELP2 | c.1772A>T p.K591I | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV100626765; called by muse, mutect2
- EXD3 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs766206273, COSV59814518; called by muse, mutect2, varscan2
- FAT4 | c.10624A>G p.N3542D | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58712604; called by muse, mutect2, varscan2
- FBN2 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1204905357, COSV52549074; called by muse, mutect2, varscan2
- FBN3 | c.8062C>T p.R2688* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as rs1012094263, COSV54475050; called by muse, mutect2, varscan2
- FBXL7 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs767178690, COSV61654436; called by muse, mutect2, varscan2
- FMN2 | c.3376G>A p.G1126R | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as rs554573414, COSV60417116; called by muse, varscan2
- GABRG2 | c.1357G>A p.D453N (on ENST00000361925 / NM_001375343.1; = p.D413N on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/407 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV62717314; called by muse, mutect2, varscan2
- GLI3 | c.4737G>T p.M1579I | Missense Mutation (SNP) | VAF 63/208 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV67895703; called by muse, mutect2, varscan2
- GPC6 | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as COSV100990137, COSV65541521; called by muse, mutect2, varscan2
- GRAMD1A | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs774467744, COSV58767297; called by muse, mutect2, varscan2
- GRIK1 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as rs746636313, COSV58717822; called by muse, mutect2, varscan2
- HDAC3 | c.477-1G>T p.X159_splice | Splice Site (SNP) | VAF 14/64 reads (22%) | catalogued as COSV59495766, COSV59498167; called by muse, mutect2, varscan2
- HSD17B2 | c.632A>G p.K211R | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.173); catalogued as COSV52275504, COSV52278940; called by muse, mutect2, varscan2
- HTR6 | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs750317366; called by mutect2, varscan2
- ITGB6 | c.759G>A p.K253= | Splice Region (SNP) | VAF 16/214 reads (7%) | catalogued as COSV99324315; called by muse, mutect2
- ITM2C | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs143044408; called by muse, mutect2, varscan2
- KIF1A | c.2770G>T p.E924* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100239792, COSV57503933; called by muse, mutect2, varscan2
- KIR3DL3 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1380734461, COSV52545531; called by muse, mutect2, varscan2
- KLRC2 | c.566G>C p.G189A | Missense Mutation (SNP) | VAF 29/322 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV67900770; called by muse, mutect2
- KMT2E | c.1345G>C p.D449H | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57580924; called by muse, mutect2
- KRT73 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.826); catalogued as rs375270968; called by muse, mutect2, varscan2
- KRTAP24-1 | c.635G>T p.S212I | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.118); catalogued as COSV61090226; called by muse, mutect2, varscan2
- LILRA1 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 88/215 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as COSV52185855; called by muse, mutect2, varscan2
- LPA | c.5185C>T p.R1729W | Missense Mutation (SNP) | VAF 53/92 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs374776600; called by muse, mutect2, varscan2
- LRRC31 | c.577A>G p.K193E | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.08); catalogued as COSV52983397; called by muse, mutect2, varscan2
- LTBP1 | c.1916G>T p.G639V (on ENST00000404816 / NM_206943.4; = p.G313V on NM_000627.4) | Missense Mutation (SNP) | VAF 24/259 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63199059; called by muse, mutect2, varscan2
- MARK1 | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs755975927, COSV65071997; called by muse, mutect2, varscan2
- MEN1 | c.320C>G p.P107R | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.402); catalogued as COSV56346719; called by muse, mutect2, varscan2
- MYPN | c.2096C>A p.A699D | Missense Mutation (SNP) | VAF 97/186 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as COSV62740864; called by muse, mutect2, varscan2
- NBAS | c.957T>A p.D319E | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55740472; called by muse, mutect2, varscan2
- NWD1 | c.1453G>T p.D485Y | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60353402; called by muse, mutect2, varscan2
- OLFML1 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs140408009, COSV55083384; called by mutect2, varscan2
- OR52D1 | c.818C>A p.P273H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59488502; called by muse, mutect2, varscan2
- OR8K5 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.043); catalogued as rs374352564, COSV57891615; called by muse, mutect2, varscan2
- PCDHA12 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV56546399; called by muse, varscan2
- PCDHAC1 | c.1700T>A p.V567E | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV53873941; called by muse, mutect2, varscan2
- PCDHB5 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.792); catalogued as rs139218724; called by muse, mutect2
- PCDHB5 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.014); catalogued as COSV50649167; called by muse, mutect2, varscan2
- PCDHGB3 | c.2146C>T p.R716* | Nonsense Mutation (SNP) | VAF 14/176 reads (8%) | catalogued as rs1208837944, COSV53894285; called by muse, mutect2
- PIGM | c.1018C>T p.L340F | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as COSV63636154; called by muse, mutect2, varscan2
- PLB1 | c.2584T>A p.L862I | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV59837413; called by muse, mutect2
- PLB1 | c.2586A>T p.L862F | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59837423; called by muse, mutect2
- POLQ | c.4289dup p.L1430Ffs*5 | Frame Shift Ins (INS) | VAF 45/100 reads (45%) | catalogued as rs755281591, COSV99951761; called by mutect2, varscan2
- PRB1 | c.804C>A p.S268R | Missense Mutation (SNP) | VAF 243/292 reads (83%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53707033; called by mutect2, varscan2
- PSTPIP1 | c.1178A>G p.E393G | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV99143620; called by muse, mutect2, varscan2
- PTCH2 | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs769934593, CM091154, COSV64711463; called by muse, mutect2, varscan2
- PTCHD1 | c.341T>A p.L114Q | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV65063196; called by muse, mutect2
- RANBP17 | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 133/354 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV66658449; called by muse, mutect2, varscan2
- RUVBL2 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV55485267; called by muse, mutect2, varscan2
- SALL3 | c.2099C>T p.T700M | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV73306707; called by muse, mutect2, varscan2
- SDC2 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774751152, COSV56226875; called by muse, mutect2, varscan2
- SIM1 | c.1800A>C p.K600N | Missense Mutation (SNP) | VAF 78/153 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.378); catalogued as COSV99492165; called by muse, mutect2, varscan2
- SLC29A4 | c.1487C>T p.T496M | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.56); catalogued as COSV51877299; called by muse, mutect2, varscan2
- SLC30A5 | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 125/274 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs768665809, COSV67450759; called by muse, mutect2, varscan2
- SLC4A3 | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56097579; called by muse, mutect2, varscan2
- SLFN5 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs748278919, COSV55482851; called by muse, mutect2, varscan2
- SNAPC2 | c.934G>C p.G312R | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54494472; called by muse, mutect2, varscan2
- SNX13 | c.1108T>C p.C370R | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.628); catalogued as COSV68068696; called by muse, mutect2
- SORCS1 | c.2114G>A p.R705Q | Missense Mutation (SNP) | VAF 109/238 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs767296473, COSV53870064; called by muse, mutect2, varscan2
- SPAG17 | c.282dup p.P95Tfs*5 | Frame Shift Ins (INS) | VAF 90/378 reads (24%) | catalogued as rs771461785; called by mutect2, varscan2
- SPATA6 | c.327G>A p.M109I | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV64064032; called by muse, mutect2, varscan2
- STAT1 | c.171T>A p.F57L | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.534); catalogued as COSV63117664; called by muse, mutect2, varscan2
- SUZ12 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 43/670 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV59503952; called by muse, mutect2
- TAS2R16 | c.832C>A p.L278M | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); catalogued as COSV50798449; called by muse, mutect2, varscan2
- TBC1D8B | c.3243G>C p.Q1081H | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.993); catalogued as COSV52184197; called by muse, mutect2, varscan2
- TDRP | c.362C>A p.A121D | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.711); catalogued as COSV100138685, COSV60707469; called by muse, mutect2
- TEX11 | c.651+1G>A p.X217_splice (on ENST00000344304; = p.X202_splice on NM_031276.3) | Splice Site (SNP) | VAF 30/117 reads (26%) | catalogued as COSV100721484; called by muse, mutect2, varscan2
- TIMD4 | c.275G>T p.R92I | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV50861683; called by muse, mutect2, varscan2
- TP73-AS1 | n.1715C>T | Splice Region (SNP) | VAF 17/60 reads (28%) | catalogued as rs373827233; called by muse, mutect2, varscan2
- TRIML2 | c.377G>T p.R126I | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV58717467, COSV58720307; called by muse, mutect2, varscan2
- USP31 | c.1865G>T p.C622F | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54858307; called by muse, mutect2, varscan2
- WDR24 | c.1180C>T p.R394C (on ENST00000248142; = p.R264C on NM_032259.4) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs1303323982, COSV50199494; called by muse, mutect2, varscan2
- ZDHHC8 | c.228G>A p.A76= | Splice Region (SNP) | VAF 21/54 reads (39%) | catalogued as rs148553691; called by muse, mutect2, varscan2
- ZNF286A | c.853A>G p.N285D | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV67846603; called by muse, mutect2, varscan2
- ZNF395 | c.1327G>T p.V443F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.668); catalogued as COSV60430632; called by muse, mutect2, varscan2
- ZNF773 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as rs781760085, COSV56588085; called by muse, mutect2, varscan2
- CERS6 | c.570_579dup p.F194Vfs*9 | Frame Shift Ins (INS) | VAF 62/360 reads (17%) | called by mutect2, varscan2
- CILP | c.235T>C p.F79L | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2
- ELF3 | c.485_486dup p.S163Afs*92 | Frame Shift Ins (INS) | VAF 19/35 reads (54%) | called by mutect2, pindel, varscan2
- LRGUK | c.1927G>C p.D643H | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.359); called by muse, mutect2
- PRR12 | c.2236G>A p.E746K (on ENST00000615927; = p.E1567K on NM_020719.3) | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); called by muse, varscan2
- ABCB1 | c.2961C>T p.A987= | Silent (SNP) | VAF 31/188 reads (16%) | catalogued as rs757389269, COSV55945915; called by muse, mutect2, varscan2
- ADGRA1 | c.189G>A p.A63= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs147537446; called by muse, mutect2, varscan2
- B4GALNT3 | c.327C>T p.N109= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV56758831; called by muse, mutect2, varscan2
- BRD4 | c.15C>T p.S5= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as rs147477529; called by muse, mutect2, varscan2
- CACNA1D | c.522C>T p.V174= | Silent (SNP) | VAF 57/228 reads (25%) | catalogued as rs773161211, COSV55440267; called by muse, mutect2, varscan2
- CC2D1A | c.825G>A p.K275= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as COSV58786662; called by muse, mutect2, varscan2
- CDH11 | c.2382C>T p.D794= | Silent (SNP) | VAF 11/151 reads (7%) | catalogued as rs377222713; called by muse, mutect2
- CSDE1 | c.1671A>G p.E557= (on ENST00000358528 / NM_001007553.3; = p.E526= on NM_007158.6) | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV54762749; called by muse, mutect2, varscan2
- FMN2 | c.609C>T p.I203= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV60420965, COSV60459751; called by muse, mutect2
- GPATCH8 | c.1092T>G p.P364= | Silent (SNP) | VAF 12/149 reads (8%) | catalogued as COSV59199461; called by muse, mutect2
- HTR2A | c.651C>T p.D217= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as rs533066466, COSV66326736; called by muse, mutect2
- KLHL42 | c.879C>T p.N293= | Silent (SNP) | VAF 63/259 reads (24%) | catalogued as rs375277321; called by muse, mutect2, varscan2
- LRP1B | c.7332C>T p.S2444= | Silent (SNP) | VAF 85/236 reads (36%) | catalogued as rs376385168; called by muse, mutect2, varscan2
- LRRC55 | c.55C>T p.L19= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV73007071; called by muse, mutect2, varscan2
- MAGEA11 | c.786G>A p.E262= | Silent (SNP) | VAF 18/206 reads (9%) | catalogued as COSV60754182; called by muse, mutect2
- MAPK8IP3 | c.3918G>A p.E1306= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs780663643, COSV51603235; called by muse, mutect2, varscan2
- MUC21 | c.1470G>A p.A490= | Silent (SNP) | VAF 86/166 reads (52%) | catalogued as rs368460700, COSV66221616; called by muse, mutect2, varscan2
- NALCN | c.4944G>A p.S1648= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs756041305, COSV51939687; called by muse, mutect2, varscan2
- NAPRT | c.597G>A p.A199= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs757491266, COSV52789402; called by muse, mutect2, varscan2
- PTPRZ1 | c.3612T>C p.S1204= | Silent (SNP) | VAF 42/190 reads (22%) | catalogued as rs1216409873, COSV66447037; called by muse, mutect2, varscan2
- TM2D3 | c.42G>A p.L14= | Silent (SNP) | VAF 17/23 reads (74%) | catalogued as COSV60109879; called by muse, mutect2, varscan2
- TRAPPC9 | c.1992C>T p.T664= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV66910949; called by muse, mutect2, varscan2
- ZNF521 | c.1461C>T p.N487= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as rs368668312; called by muse, mutect2, varscan2
- BTBD11 | c.*2A>T | 3'UTR (SNP) | VAF 10/70 reads (14%) | catalogued as COSV99775203; called by muse, mutect2, varscan2
- CCNQP1 | n.435C>T | RNA (SNP) | VAF 17/75 reads (23%) | catalogued as rs367808812; called by muse, mutect2, varscan2
